Somatic mutation profile of tumor specimen 0E0841 from CCDI case PBCUPL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0841: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9cd9be9-476e-4c6f-9ead-680feef63ef7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E084E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eda69a0-b531-4cc2-980a-5881229eab2d

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Splice Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD1B | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 32/903 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); catalogued as rs1021805831, COSV63804675; called by muse, mutect2
- DOLPP1 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 43/579 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as rs375613874; called by muse, mutect2
- TMPRSS6 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 140/302 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs146063847; called by muse, mutect2, varscan2
- CACNA1S | c.4680_4707del p.T1561Sfs*64 | Frame Shift Del (DEL) | VAF 158/380 reads (42%) | called by mutect2, varscan2
- KIF1B | c.2116-1G>A p.X706_splice (on ENST00000377086 / NM_001365952.1; = p.X660_splice on NM_015074.3) | Splice Site (SNP) | VAF 82/640 reads (13%) | called by mutect2, varscan2
- MYH1 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 60/479 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PRX | c.1245G>A p.L415= | Silent (SNP) | VAF 13/292 reads (4%) | called by muse, mutect2
- SMARCD2 | c.1275C>G p.A425= | Silent (SNP) | VAF 137/888 reads (15%) | called by muse, mutect2, varscan2
- EPM2A | c.-14C>T | 5'UTR (SNP) | VAF 7/128 reads (5%) | catalogued as rs1421723495; called by muse, mutect2
